Somatic mutation profile of tumor specimen 0DCER3 from CCDI case PBBMJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,905 days).
Specimen 0DCER3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 812f8ae5-3ec3-46e8-8f75-23eda3f4f8d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCEQY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/482cf3f9-3688-4324-ad54-40724bd1f3f8

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 217/732 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.4447T>C p.C1483R | Missense Mutation (SNP) | VAF 65/831 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1057519914, COSV63875155; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- IL17F | c.122dup p.Q42Pfs*4 | Frame Shift Ins (INS) | VAF 92/690 reads (13%) | catalogued as rs771763707; called by mutect2, pindel, varscan2
- KMT2A | c.5291G>A p.R1764H | Missense Mutation (SNP) | VAF 169/530 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1555043444, COSV63282001; called by muse, mutect2, varscan2
- OR8I2 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 42/1330 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1286826012; called by muse, mutect2
- ABCA6 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 52/800 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2
- DDX3X | c.1152_1153insATT p.F384_P385insI (on ENST00000399959; = p.F385_P386insI on NM_001356.5) | In Frame Ins (INS) | VAF 135/280 reads (48%) | called by mutect2, pindel, varscan2
- DDX3X | c.1514A>G p.D505G (on ENST00000399959; = p.D506G on NM_001356.5) | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- FOXO3 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
- MAPK8IP3 | c.2794T>C p.S932P | Missense Mutation (SNP) | VAF 22/844 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CSNK2B | c.609C>T p.A203= | Silent (SNP) | VAF 32/620 reads (5%) | called by muse, mutect2
- PSEN1 | c.21G>A p.P7= | Silent (SNP) | VAF 179/483 reads (37%) | catalogued as rs116466962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACFD1 | c.*10C>T | 3'UTR (SNP) | VAF 30/1054 reads (3%) | catalogued as rs781793507; called by muse, mutect2
- CZIB | c.90+38C>T | Intron (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- ZFAND2B | c.151-52_151-51del | Intron (DEL) | VAF 156/510 reads (31%) | called by pindel, varscan2
